Somatic mutation profile of tumor specimen C3L-01146-02 (aliquot CPT0218690007) from CPTAC case C3L-01146, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.0 years (21,566 days).
Specimen C3L-01146-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa1d0e54-3d85-4390-8e7d-9b2b34a8a9b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01146-31 (Blood Derived Normal), aliquot CPT0220330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/791c7fcb-2594-4737-bf67-3eb886cba5fc

The open-access MAF lists 89 somatic variants for this specimen: 66 protein-altering or splice-affecting, 16 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 16, Nonsense Mutation 5, Intron 3, RNA 3, Splice Site 3, Frame Shift Del 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.4332+1G>A p.X1444_splice (on ENST00000358273 / NM_001042492.3; = p.X1423_splice on NM_000267.3) | Splice Site (SNP) | VAF 39/233 reads (17%) | catalogued as rs1555618572, CD072444, CS068231, CS072254, COSV100648631, COSV62211652; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 114/427 reads (27%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1520C>A p.T507K | Missense Mutation (SNP) | VAF 254/880 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs886039463, CM090464, COSV104418166, COSV61005528; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs755088665, COSV52210429, COSV52211116; called by muse, mutect2
- AC005833.1 | c.1586G>A p.C529Y | Missense Mutation (SNP) | VAF 62/360 reads (17%) | SIFT deleterious, low confidence (0); catalogued as rs576017644; called by muse, mutect2, varscan2
- ACTR1A | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 126/448 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1184467444, COSV64023480; called by muse, mutect2, varscan2
- ANGEL2 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs771489874, COSV64737240; called by muse, mutect2, varscan2
- APOBEC3H | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 71/373 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.084); catalogued as rs750601192; called by muse, mutect2, varscan2
- AVPR1A | c.1157del p.T386Ifs*41 | Frame Shift Del (DEL) | VAF 71/465 reads (15%) | catalogued as rs1438988595; called by mutect2, pindel, varscan2
- CAPN13 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750746660, COSV54435635; called by muse, mutect2, varscan2
- CDK18 | c.688G>A p.A230T (on ENST00000506784 / NM_212503.3; = p.A200T on NM_002596.4) | Missense Mutation (SNP) | VAF 173/557 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs373562577, COSV63727446; called by muse, mutect2, varscan2
- COG7 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 150/597 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs149289920; called by mutect2, varscan2
- DNAH3 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs763248461, COSV54555861; called by muse, mutect2, varscan2
- EGF | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 80/370 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764312466, COSV54480294; called by muse, mutect2, varscan2
- FAM83B | c.2879G>A p.R960H | Missense Mutation (SNP) | VAF 61/292 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs568321920, COSV60921736; called by muse, mutect2, varscan2
- FLT4 | c.2293G>A p.V765M | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56122101; called by muse, mutect2, varscan2
- FNDC1 | c.2411C>T p.T804M | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as rs1262947803, COSV51938908; called by muse, mutect2, varscan2
- GJA10 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs977098948; called by muse, mutect2, varscan2
- GPR132 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs753534917, COSV61678008; called by muse, mutect2, varscan2
- KLK6 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 120/421 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.154); catalogued as rs755504009, COSV100037885; called by muse, mutect2, varscan2
- LRRC7 | c.1583G>A p.R528H (on ENST00000651989 / NM_001370785.2; = p.R495H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as rs750231315, COSV50488265; called by muse, mutect2, varscan2
- LRTM2 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs919752328; called by muse, mutect2, varscan2
- MSH4 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 55/340 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1244992679, COSV54202522; called by muse, mutect2, varscan2
- MTUS2 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1443904265, COSV70912573; called by muse, mutect2, varscan2
- NLRP8 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.201); catalogued as rs765907009, COSV99404735; called by muse, mutect2, varscan2
- NPSR1 | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 70/516 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs149663215; called by muse, mutect2, varscan2
- OR10J5 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs146863607, COSV58385033; called by muse, mutect2, varscan2
- PGR | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 224/954 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs767505462, COSV54796073; called by muse, mutect2, varscan2
- PLEKHG3 | c.1315C>T p.R439C (on ENST00000394691; = p.R495C on NM_001308147.2) | Missense Mutation (SNP) | VAF 86/453 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs375116826; called by muse, mutect2, varscan2
- PPP1R16B | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 76/392 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs916682056, COSV104410043; called by muse, mutect2, varscan2
- PPP1R26 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 105/321 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.683); catalogued as rs147273345; called by muse, mutect2, varscan2
- PTER | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.895); catalogued as rs767872311; called by muse, mutect2, varscan2
- RIMBP2 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 152/457 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as rs201181586, COSV55480180; called by muse, mutect2, varscan2
- RYR2 | c.9779G>A p.R3260Q | Missense Mutation (SNP) | VAF 142/365 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as rs750415021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC17A8 | c.1352G>A p.G451E | Missense Mutation (SNP) | VAF 268/861 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60123154; called by muse, mutect2, varscan2
- SLC6A6 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 153/520 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770780822, COSV62651087; called by muse, mutect2, varscan2
- SRCIN1 | c.3353G>A p.R1118H (on ENST00000621492; = p.R1084H on NM_025248.3) | Missense Mutation (SNP) | VAF 83/408 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs564541937; called by muse, mutect2, varscan2
- TENM3 | c.5263C>T p.Q1755* | Nonsense Mutation (SNP) | VAF 70/379 reads (18%) | catalogued as COSV69309825; called by muse, mutect2, varscan2
- TMEM132D | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 242/702 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs756539559, COSV70601435, COSV70624212; called by muse, mutect2, varscan2
- TRPM6 | c.841+1G>A p.X281_splice | Splice Site (SNP) | VAF 140/798 reads (18%) | catalogued as rs371363425; called by muse, mutect2, varscan2
- TUBB6 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 138/705 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.262); catalogued as COSV52316990; called by muse, mutect2, varscan2
- ZNF497 | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.462); catalogued as rs1174561620; called by muse, mutect2, varscan2
- ABCC6 | c.2972T>G p.F991C | Missense Mutation (SNP) | VAF 188/830 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ALPK2 | c.1267T>C p.S423P | Missense Mutation (SNP) | VAF 91/448 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ASCC3 | c.2824A>T p.I942F | Missense Mutation (SNP) | VAF 55/288 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC158 | c.2083A>T p.N695Y | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCP110 | c.2227+2T>G p.X743_splice | Splice Site (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- CELSR1 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 65/260 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CHRNB2 | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 119/658 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTNAP3 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 232/610 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0.009); called by muse, varscan2
- COL22A1 | c.1670G>C p.G557A | Missense Mutation (SNP) | VAF 66/449 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPI | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 117/789 reads (15%) | called by muse, mutect2, varscan2
- HAS1 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 126/748 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KLF14 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LRRC69 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED30 | c.94T>C p.S32P | Missense Mutation (SNP) | VAF 65/460 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MX1 | c.1495C>T p.H499Y | Missense Mutation (SNP) | VAF 58/347 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NF1 | c.3861_3862del p.F1287Lfs*26 | Frame Shift Del (DEL) | VAF 66/379 reads (17%) | called by mutect2, pindel, varscan2
- OR9A4 | c.743T>G p.V248G | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLAT | c.13A>T p.K5* | Nonsense Mutation (SNP) | VAF 58/439 reads (13%) | called by muse, mutect2, varscan2
- SIM2 | c.1039G>C p.V347L | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK4 | c.110A>T p.N37I | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TTI2 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 110/794 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBE2Z | c.778A>T p.K260* | Nonsense Mutation (SNP) | VAF 66/316 reads (21%) | called by muse, mutect2, varscan2
- ZBTB7A | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 92/333 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- ZNF423 | c.2915G>C p.C972S (on ENST00000563137 / NM_001379286.1; = p.C964S on NM_015069.4) | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCG8 | c.360C>T p.G120= | Silent (SNP) | VAF 222/965 reads (23%) | called by muse, mutect2, varscan2
- AMIGO3 | c.1275G>T p.P425= | Silent (SNP) | VAF 205/1111 reads (18%) | called by muse, mutect2, varscan2
- CLEC10A | c.864C>T p.D288= (on ENST00000254868 / NM_182906.4; = p.D264= on NM_006344.4) | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs372729049; called by muse, mutect2, varscan2
- FAM135B | c.72G>A p.Q24= | Silent (SNP) | VAF 66/191 reads (35%) | called by muse, mutect2, varscan2
- FAM83C | c.1056G>A p.K352= | Silent (SNP) | VAF 30/470 reads (6%) | catalogued as rs1238822028; called by muse, mutect2
- LTBP4 | c.4452C>T p.G1484= (on ENST00000308370 / NM_001042544.1; = p.G1447= on NM_003573.2) | Silent (SNP) | VAF 43/257 reads (17%) | catalogued as rs904645684, COSV52589203; called by muse, mutect2, varscan2
- MAP3K19 | c.144C>T p.F48= | Silent (SNP) | VAF 94/267 reads (35%) | catalogued as rs749805940, COSV59636777; called by muse, mutect2, varscan2
- MTOR | c.3519C>T p.A1173= | Silent (SNP) | VAF 56/273 reads (21%) | catalogued as rs573946790; called by muse, mutect2, varscan2
- OR7G1 | c.99C>T p.S33= | Silent (SNP) | VAF 72/223 reads (32%) | catalogued as COSV99528672; called by muse, mutect2, varscan2
- PCDHGA4 | c.318C>T p.F106= | Silent (SNP) | VAF 64/314 reads (20%) | catalogued as COSV53902032; called by muse, mutect2, varscan2
- PTH1R | c.1587C>T p.N529= | Silent (SNP) | VAF 40/227 reads (18%) | catalogued as rs199557895; called by muse, mutect2, varscan2
- REP15 | c.669C>T p.D223= | Silent (SNP) | VAF 54/161 reads (34%) | catalogued as rs748052599; called by muse, mutect2, varscan2
- SMPD3 | c.807C>T p.N269= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as rs892110854, COSV54710136; called by muse, mutect2, varscan2
- WDR90 | c.2841C>T p.A947= | Silent (SNP) | VAF 62/366 reads (17%) | catalogued as rs554240383; called by muse, mutect2, varscan2
- XKR7 | c.1242G>A p.S414= | Silent (SNP) | VAF 65/330 reads (20%) | catalogued as rs1197757286, COSV73813331; called by muse, mutect2, varscan2
- ZG16 | c.48C>T p.G16= | Silent (SNP) | VAF 75/382 reads (20%) | called by muse, mutect2, varscan2
- AC009533.1 | n.399A>C | RNA (SNP) | VAF 10/76 reads (13%) | called by mutect2, varscan2
- AGPAT4 | c.843+2388G>C | Intron (SNP) | VAF 56/195 reads (29%) | called by muse, mutect2, varscan2
- CCDC198 | c.656-3956G>A | Intron (SNP) | VAF 3/31 reads (10%) | catalogued as rs1453630298; called by muse, mutect2
- IGKV3-15 | c.-12C>T | 5'UTR (SNP) | VAF 71/402 reads (18%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1665T>C | RNA (SNP) | VAF 23/139 reads (17%) | called by muse, mutect2, varscan2
- RPS6KA1 | c.109-968G>A | Intron (SNP) | VAF 76/370 reads (21%) | catalogued as rs760892746; called by muse, mutect2, varscan2
- SCOC-AS1 | n.415G>T | RNA (SNP) | VAF 49/190 reads (26%) | called by muse, mutect2, varscan2
